Gene-level copy-number profile of tumor specimen TCGA-4G-AAZG-01A from TCGA case TCGA-4G-AAZG, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 75.3 years (27,490 days).
Specimen TCGA-4G-AAZG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cf2acbd0-4a92-41f2-807a-252c0dba7196.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-4G-AAZG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/63eb515c-e9be-4443-9218-06fe4b0a59ed

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 108; copy number 1: 6,254; copy number 2: 23,900; copy number 3: 25,895; copy number 4: 2,752.

Homozygous deletions (total copy number 0; autosomes only): 108 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,309,898–89,600,680, 4 genes: IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr6:60,281,444–60,546,660, 1 gene: AC244258.1.
- chr6:165,279,664–166,209,506, 13 genes: C6orf118, PDE10A, RNA5SP226, RNU6-730P, AL590302.2, AL590302.1, LINC00602, GAPDHP72, AL627443.1, AL627443.2, TBXT, LNCDAT, RNU6-153P.
- chr9:21,394,888–22,214,672, 30 genes: AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:59,955,430–60,733,490, 6 genes (within-gene range 0–2): LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1.
- chr14:102,777,449–103,847,575, 47 genes: TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1, RPL13P6, AL161669.1, EXOC3L4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13, RAP2CP1, AL138976.1, AL138976.2, EIF5, SNORA28, HMGB3P26, RPSAP5, MARK3, RPL10AP1, CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5, KLC1, COA8, AL139300.1, RNU4-68P, AL049840.2, AL049840.6, AL049840.3, AL049840.4, AL049840.5, XRCC3, ZFYVE21, Y_RNA, PPP1R13B, AL049840.7, AL049840.1.
- chr15:19,878,555–19,887,814, 2 genes: AC138701.1, RNU6-978P.
- chr20:30,484,925–30,816,274, 4 genes: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,047. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
